Gene-level copy-number profile of tumor specimen TARGET-20-PASEGC-09A from TARGET case TARGET-20-PASEGC, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.8 years (4,312 days).
Specimen TARGET-20-PASEGC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.6070d773-299b-5bb9-aefc-e1ab230c86fc.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PASEGC-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate.
https://portal.gdc.cancer.gov/files/badebb44-1bbc-4ebc-bf75-3b3d4c005e1e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 10; copy number 2: 59,531; copy number 3: 168; copy number 5: 42.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 42 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 5 (within-gene range 2–5): AC244205.1.
- chr2:88,857,161–89,245,596, 38 genes, copy number 5: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr5:32,103,445–32,174,319, 3 genes, copy number 5 (within-gene range 2–5): AC025178.1, GOLPH3, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
